Somatic mutation profile of tumor specimen TCGA-BG-A18B-01A (aliquot TCGA-BG-A18B-01A-11D-A12J-09) from TCGA case TCGA-BG-A18B, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 53.5 years (19,550 days).
Specimen TCGA-BG-A18B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2e26ca7-7f31-412b-91f3-8ac1643af83d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A18B-10A (Blood Derived Normal), aliquot TCGA-BG-A18B-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bcb1330-cd13-444a-87e5-d74cc401da95

The open-access MAF lists 451 somatic variants for this specimen: 363 protein-altering or splice-affecting, 79 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 222, Frame Shift Del 84, Silent 79, Frame Shift Ins 28, Nonsense Mutation 20, Splice Site 8, Intron 6, 3'UTR 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 51/115 reads (44%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, mutect2, varscan2
- DYRK1A | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 62/191 reads (32%) | catalogued as rs797044523; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 80/164 reads (49%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 127/293 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1699A>G p.K567E (on ENST00000521381 / NM_181523.3; = p.K297E on NM_181504.4) | Missense Mutation (SNP) | VAF 139/301 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV57123609; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 200/227 reads (88%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB5 | c.1709C>T p.A570V (on ENST00000404938 / NM_001163941.2; = p.A125V on NM_178559.6) | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.249); catalogued as rs150650141; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 72/178 reads (40%) | catalogued as rs757016425; called by mutect2, varscan2
- AFAP1 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs200872291; called by muse, mutect2, varscan2
- AFG1L | c.470G>A p.R157K | Missense Mutation (SNP) | VAF 96/231 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV64555738; called by muse, mutect2, varscan2
- AGPAT4 | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV57245948; called by muse, mutect2, varscan2
- AGXT | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.929); catalogued as COSV56754016; called by muse, mutect2, varscan2
- AHNAK2 | c.15415G>A p.G5139R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0.059); catalogued as rs368740292; called by muse, mutect2, varscan2
- AKAP13 | c.3677G>A p.S1226N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV63457022; called by muse, mutect2
- AKAP6 | c.4048G>A p.A1350T | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs138243272; called by muse, mutect2, varscan2
- ALDOB | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV66397816; called by muse, mutect2, varscan2
- ANKIB1 | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.592); catalogued as COSV56061413; called by muse, mutect2, varscan2
- ANKRD11 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV56360869; called by muse, mutect2, varscan2
- ANKRD26 | c.2266dup p.M756Nfs*6 | Frame Shift Ins (INS) | VAF 125/338 reads (37%) | catalogued as rs1358981338, COSV65775272; called by mutect2, varscan2
- ANKS3 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs961056150, COSV58508946; called by muse, mutect2, varscan2
- ANO8 | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs771051319, COSV50173913; called by muse, mutect2, varscan2
- ANPEP | c.1675G>T p.G559W | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55591489, COSV55593493; called by muse, mutect2, varscan2
- AP3M1 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV62331323; called by muse, mutect2, varscan2
- ARHGAP10 | c.1505T>C p.L502P | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60599333; called by muse, mutect2, varscan2
- ARHGAP29 | c.995G>A p.C332Y | Missense Mutation (SNP) | VAF 139/324 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53111555; called by muse, mutect2, varscan2
- ARID1A | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 119/270 reads (44%) | catalogued as COSV61377632; called by muse, mutect2, varscan2
- ARID2 | c.1169T>A p.L390* | Nonsense Mutation (SNP) | VAF 21/208 reads (10%) | catalogued as COSV57599477, COSV57603708, COSV57618465; called by muse, mutect2, varscan2
- ARL10 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53798882; called by muse, mutect2, varscan2
- ASIC4 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs547428677, COSV61731794; called by muse, mutect2, varscan2
- ASPA | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 123/311 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV53981132; called by muse, mutect2, varscan2
- ASXL1 | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 221/465 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60107916; called by muse, mutect2
- ATG13 | c.1459T>C p.S487P (on ENST00000359513 / NM_001346321.1; = p.S450P on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56319387; called by muse, mutect2, varscan2
- ATP1A4 | c.269del p.P90Hfs*51 | Frame Shift Del (DEL) | VAF 82/221 reads (37%) | catalogued as rs767149479; called by mutect2, pindel, varscan2
- ATP2C1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 26/462 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs182847851, COSV60756429; called by muse, mutect2
- AXIN2 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 152/332 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV61056352, COSV61057569; called by muse, mutect2, varscan2
- B4GALT2 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766675284, COSV58842758; called by muse, mutect2, varscan2
- BEX3 | c.280A>G p.M94V | Missense Mutation (SNP) | VAF 88/197 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV55421267; called by muse, mutect2, varscan2
- BHMT2 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs763225133, COSV54872258; called by muse, mutect2, varscan2
- BRD1 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs540561914, COSV53457366; called by muse, mutect2, varscan2
- BTBD17 | c.1378C>A p.L460M | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64729788; called by muse, mutect2, varscan2
- C19orf47 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 78/162 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs376597651; called by muse, mutect2, varscan2
- C8A | c.1342A>G p.R448G | Missense Mutation (SNP) | VAF 118/296 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100776399; called by mutect2, varscan2
- CACNA2D4 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 117/256 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs779055186, COSV54950154; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAD | c.1910G>A p.S637N | Missense Mutation (SNP) | VAF 84/199 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53026812; called by muse, mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | catalogued as rs745547658; called by mutect2, varscan2
- CAPN6 | c.1490T>C p.L497P | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV60694999; called by muse, mutect2, varscan2
- CCAR1 | c.2971G>T p.E991* | Nonsense Mutation (SNP) | VAF 104/216 reads (48%) | catalogued as COSV56269846; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 66/152 reads (43%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC9B | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV66875430; called by muse, mutect2, varscan2
- CD160 | c.371A>G p.Q124R | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as COSV52522859; called by muse, mutect2, varscan2
- CDC42EP4 | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as rs868508363, COSV59962150, COSV59962845; called by muse, mutect2, varscan2
- CDKN2D | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV57264573; called by muse, mutect2, varscan2
- CEP128 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 100/264 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138323270; called by muse, mutect2, varscan2
- CETP | c.1364T>C p.V455A | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as COSV52362558; called by muse, mutect2, varscan2
- CFAP126 | c.227del p.P76Lfs*4 | Frame Shift Del (DEL) | VAF 48/140 reads (34%) | catalogued as rs780823798; called by mutect2, pindel, varscan2
- CFAP43 | c.3878A>G p.K1293R | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.723); catalogued as COSV63853118; called by muse, mutect2, varscan2
- CHST6 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1280090242, COSV60000123; called by mutect2, varscan2
- CLEC16A | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.257); catalogued as rs1037578677, COSV68499500; called by muse, mutect2, varscan2
- CNNM2 | c.274del p.A92Rfs*4 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as rs768722573; called by mutect2, varscan2
- COL15A1 | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.06); catalogued as COSV66644713; called by muse, mutect2, varscan2
- COL22A1 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225221507, COSV57336822; called by muse, mutect2
- CPD | c.2142G>C p.M714I | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56712833; called by muse, mutect2, varscan2
- CREBBP | c.4211G>T p.G1404V | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437164037, COSV52123821; called by muse, mutect2, varscan2
- CRY2 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV69888548; called by muse, mutect2, varscan2
- CSMD3 | c.3901G>C p.D1301H (on ENST00000297405 / NM_001363185.1; = p.D1197H on NM_052900.3) | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52180133, COSV52316033; called by muse, mutect2, varscan2
- CTTN | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 50/105 reads (48%) | catalogued as rs776466770, COSV57232297; called by muse, mutect2, varscan2
- CUX1 | c.3742C>T p.R1248W | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52899602; called by muse, mutect2, varscan2
- CYP2A6 | c.1178C>A p.P393H | Missense Mutation (SNP) | VAF 106/231 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56535213; called by muse, mutect2, varscan2
- DGAT2 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV57176256; called by muse, mutect2, varscan2
- DISP3 | c.3805dup p.H1269Pfs*115 | Frame Shift Ins (INS) | VAF 8/25 reads (32%) | catalogued as rs756156984; called by mutect2, varscan2
- DLGAP2 | c.1976G>A p.G659D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV70098188; called by muse, mutect2, varscan2
- DMPK | c.848C>T p.T283M | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs774774759, COSV52178225; called by muse, mutect2, varscan2
- DMRT3 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs752829841, COSV51904535; called by muse, mutect2, varscan2
- DMXL1 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as rs753048695, COSV60711410; called by muse, mutect2, varscan2
- DNAH17 | c.609G>T p.Q203H | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs766239541, COSV67753684, COSV67754324; called by muse, mutect2, varscan2
- DNAJC11 | c.624G>T p.W208C | Missense Mutation (SNP) | VAF 84/189 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53786724; called by muse, mutect2, varscan2
- DOCK2 | c.3694C>A p.L1232M | Missense Mutation (SNP) | VAF 103/221 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV56958641; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 60/159 reads (38%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DRAM1 | c.321G>T p.M107I | Missense Mutation (SNP) | VAF 269/626 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as COSV51597812; called by muse, mutect2
- DRAXIN | c.548G>A p.S183N | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as COSV53843256; called by muse, mutect2, varscan2
- DYNC1I2 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55526035; called by muse, mutect2, varscan2
- DYNC1I2 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 96/230 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.706); catalogued as COSV55526045; called by muse, mutect2, varscan2
- DZIP3 | c.2361G>T p.K787N | Missense Mutation (SNP) | VAF 65/190 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV64312087; called by muse, mutect2, varscan2
- EEF2K | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs747658944, COSV53779724; called by muse, mutect2, varscan2
- EGR2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV54346848, COSV54346961; called by muse, mutect2, varscan2
- EIF3M | c.462G>T p.W154C | Missense Mutation (SNP) | VAF 131/309 reads (42%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.993); catalogued as COSV60072630; called by muse, mutect2, varscan2
- ENGASE | c.1946T>C p.L649P | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100285607; called by muse, mutect2, varscan2
- EPHA8 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776511588, COSV51268352; called by muse, mutect2, varscan2
- ERBB3 | c.3194C>T p.S1065F | Missense Mutation (SNP) | VAF 188/436 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV57253269; called by muse, mutect2, varscan2
- ESPL1 | c.1715G>A p.S572N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.628); catalogued as COSV99228658; called by muse, mutect2, varscan2
- ESYT3 | c.1861G>T p.E621* | Nonsense Mutation (SNP) | VAF 71/137 reads (52%) | catalogued as COSV67440875; called by muse, mutect2, varscan2
- EZR | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as rs767132690, COSV51910355; called by muse, mutect2, varscan2
- FAAH2 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV66507617; called by muse, mutect2, varscan2
- FAM189B | c.1511-1G>T p.X504_splice | Splice Site (SNP) | VAF 140/306 reads (46%) | catalogued as COSV59169731; called by muse, mutect2, varscan2
- FAM47B | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 73/148 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs773159030, COSV61452348; called by muse, mutect2, varscan2
- FASTKD3 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs768954890, COSV52943849; called by muse, mutect2, varscan2
- FBXO7 | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 265/562 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs762037477, COSV56677997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FERD3L | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 21/34 reads (62%) | catalogued as rs749275441, COSV51762704; called by muse, mutect2, varscan2
- FEZ2 | c.938dup p.N313Kfs*7 | Frame Shift Ins (INS) | VAF 82/196 reads (42%) | catalogued as rs759258050; called by mutect2, varscan2
- FFAR1 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as COSV50052720; called by muse, mutect2, varscan2
- FGF8 | c.276C>A p.N92K (on ENST00000344255 / NM_033164.4; = p.N74K on NM_006119.6) | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); catalogued as COSV100199453, COSV60142832; called by muse, mutect2, varscan2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | catalogued as rs769482947; called by mutect2, varscan2
- FMNL3 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs377232039; called by muse, mutect2, varscan2
- FOSL1 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs947657834, COSV57028001; called by muse, varscan2
- FOXG1 | c.1295del p.T432Sfs*3 | Frame Shift Del (DEL) | VAF 28/65 reads (43%) | catalogued as COSV57396799; called by mutect2, pindel, varscan2
- FUBP3 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 68/146 reads (47%) | catalogued as rs760166472, COSV60513868; called by muse, mutect2, varscan2
- FYB2 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 91/174 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.242); catalogued as COSV58585143; called by muse, mutect2, varscan2
- FZD7 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as rs1202884817, COSV53809406; called by muse, mutect2, varscan2
- GJD2 | c.427A>G p.K143E | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV51748183; called by muse, mutect2, varscan2
- GOLGA6B | c.1708A>G p.T570A | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.078); catalogued as rs757990928, COSV69770121; called by mutect2, varscan2
- GOT1L1 | c.604A>G p.M202V | Missense Mutation (SNP) | VAF 108/270 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56875645; called by muse, mutect2, varscan2
- GPR3 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as COSV64994701; called by muse, mutect2, varscan2
- GRIK4 | c.1809del p.F604Sfs*27 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as COSV70801839; called by mutect2, pindel, varscan2
- GRIN2B | c.1501-1G>T p.X501_splice | Splice Site (SNP) | VAF 50/137 reads (36%) | catalogued as COSV74205922; called by muse, mutect2, varscan2
- GRIN2C | c.1207C>A p.L403M | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV53112295; called by muse, mutect2, varscan2
- GRIP2 | c.2960G>T p.R987M (on ENST00000619221; = p.R890M on NM_001080423.4) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56121386; called by muse, mutect2, varscan2
- GRK7 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as COSV53822947; called by muse, mutect2, varscan2
- H4C6 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV66685553; called by muse, mutect2, varscan2
- HACD4 | c.271-1G>A p.X91_splice | Splice Site (SNP) | VAF 16/250 reads (6%) | catalogued as COSV72136710; called by muse, mutect2
- HECW1 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV67829480; called by muse, mutect2, varscan2
- HELQ | c.1682dup p.M562Dfs*4 | Frame Shift Ins (INS) | VAF 72/195 reads (37%) | catalogued as rs1560552678; called by mutect2, pindel, varscan2
- HEXA | c.409C>G p.R137G | Missense Mutation (SNP) | VAF 88/206 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM910215, COSV51505186, COSV51506430; called by muse, mutect2, varscan2
- HEY2 | c.328_328+27del p.X110_splice | Splice Site (DEL) | VAF 31/108 reads (29%) | catalogued as COSV64239883; called by mutect2, pindel, varscan2
- HIBADH | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 120/335 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV55313864; called by muse, mutect2, varscan2
- HIVEP1 | c.6539C>T p.S2180F | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779406597, COSV65101403; called by muse, mutect2, varscan2
- HS3ST3A1 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV52375471; called by mutect2, varscan2
- HSD17B12 | c.650A>G p.H217R | Missense Mutation (SNP) | VAF 411/958 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs766128479, COSV53499552; called by muse, mutect2, varscan2
- IBTK | c.226G>T p.V76L | Missense Mutation (SNP) | VAF 100/244 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as COSV60392880; called by muse, mutect2, varscan2
- IGF2BP1 | c.1227G>T p.Q409H | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51731282, COSV51735343; called by muse, mutect2, varscan2
- IGSF9 | c.1748G>A p.S583N (on ENST00000368094 / NM_001135050.2; = p.S567N on NM_020789.4) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1418986148, COSV63640078; called by muse, mutect2, varscan2
- IL2RG | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.121); catalogued as COSV52148408; called by muse, mutect2, varscan2
- INTS11 | c.528+1G>A p.X176_splice | Splice Site (SNP) | VAF 60/137 reads (44%) | catalogued as rs1334049577, COSV60088294; called by muse, mutect2, varscan2
- ITM2B | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV66035162; called by muse, mutect2, varscan2
- KL | c.1811C>A p.P604H | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751229348, COSV66308772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLF5 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV66614437; called by muse, mutect2, varscan2
- KLHL10 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 112/256 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as rs781951302, COSV53172679; called by muse, mutect2, varscan2
- KLHL28 | c.1116G>A p.M372I | Missense Mutation (SNP) | VAF 113/254 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV61888150; called by muse, mutect2, varscan2
- KLHL8 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 123/257 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as rs1015568507, COSV56747808; called by muse, mutect2, varscan2
- KMT2D | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 120/264 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.251); catalogued as rs201512665, COSV56411235; called by muse, mutect2, varscan2
- KRT27 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV56971777; called by muse, mutect2, varscan2
- KRT37 | c.944G>A p.C315Y | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56658051; called by muse, mutect2, varscan2
- KRT85 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 97/226 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV57736871; called by muse, mutect2, varscan2
- KSR2 | c.1606del p.L536Sfs*61 | Frame Shift Del (DEL) | VAF 131/340 reads (39%) | catalogued as rs770565486; called by pindel, varscan2
- KY | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752417594, COSV71017284; called by muse, mutect2, varscan2
- LAX1 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs779557724, COSV65848782; called by muse, mutect2, varscan2
- LIN7A | c.152A>G p.Q51R | Missense Mutation (SNP) | VAF 164/387 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); catalogued as COSV54021373; called by muse, mutect2, varscan2
- LIN9 | c.1081C>T p.R361W (on ENST00000366808 / NM_001270410.2; = p.R306W on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 128/269 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60243786; called by muse, mutect2, varscan2
- LLGL1 | c.2869G>A p.A957T | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV57497944; called by muse, mutect2, varscan2
- LRP1 | c.3523G>A p.G1175S | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as rs143746304; called by muse, mutect2, varscan2
- LRRC10 | c.714del p.R239Dfs*92 | Frame Shift Del (DEL) | VAF 46/112 reads (41%) | catalogued as COSV100825506; called by mutect2, pindel, varscan2
- LRRC6 | c.845dup p.K283Efs*12 | Frame Shift Ins (INS) | VAF 196/528 reads (37%) | catalogued as rs1391729028; called by mutect2, varscan2
- LTN1 | c.4275T>A p.D1425E | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.278); catalogued as COSV63733804; called by muse, mutect2, varscan2
- LYST | c.7018G>A p.V2340I | Missense Mutation (SNP) | VAF 99/227 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs540634120, COSV67706990; called by muse, mutect2, varscan2
- MAN2A1 | c.1513A>G p.S505G | Missense Mutation (SNP) | VAF 103/235 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54851552; called by muse, mutect2, varscan2
- MARVELD3 | c.948del p.Y317Tfs*45 | Frame Shift Del (DEL) | VAF 56/150 reads (37%) | catalogued as rs747980715, COSV51704302; called by mutect2, pindel, varscan2
- MBNL3 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 136/260 reads (52%) | catalogued as COSV63730853; called by muse, mutect2, varscan2
- MCCC2 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 152/340 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); catalogued as rs547662164, CM010914, COSV60154428, COSV60154870; called by muse, mutect2, varscan2
- MED12 | c.3412C>T p.R1138W | Missense Mutation (SNP) | VAF 115/260 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61339953, COSV61342433; called by muse, mutect2, varscan2
- MEPCE | c.2030C>A p.P677H | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV52769209; called by muse, mutect2, varscan2
- MICOS13 | c.241C>A p.R81S | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.331); catalogued as COSV56797963, COSV56798356; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 36/95 reads (38%) | catalogued as rs750307488; called by mutect2, varscan2
- MLLT3 | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 21/310 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs201817828, COSV100581529; called by muse, mutect2
- MNS1 | c.997A>T p.K333* | Nonsense Mutation (SNP) | VAF 184/432 reads (43%) | catalogued as COSV53068323; called by muse, mutect2, varscan2
- MOV10 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | catalogued as COSV54145332; called by muse, mutect2, varscan2
- MUC5B | c.11006G>A p.G3669D | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as COSV71591313; called by muse, mutect2, varscan2
- MVD | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55368328; called by muse, mutect2, varscan2
- MYH3 | c.1945T>G p.S649A | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.221); catalogued as COSV56864920; called by muse, mutect2, varscan2
- MYH6 | c.5307G>T p.E1769D | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV59305867; called by muse, mutect2, varscan2
- MYH9 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs151240427; called by muse, mutect2, varscan2
- MYLK3 | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 90/233 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as rs769993017, COSV67364252; called by muse, mutect2, varscan2
- MYO18A | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs545694175, COSV62866383; called by muse, mutect2, varscan2
- NAMPT | c.1403C>T p.T468I | Missense Mutation (SNP) | VAF 157/402 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV55995119; called by muse, mutect2, varscan2
- NCAPH2 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs139403039; called by muse, mutect2, varscan2
- NCKAP5L | c.1815dup p.S606Qfs*204 | Frame Shift Ins (INS) | VAF 11/25 reads (44%) | catalogued as rs1160641782; called by mutect2, pindel, varscan2
- NDST4 | c.1621C>T p.Q541* | Nonsense Mutation (SNP) | VAF 119/267 reads (45%) | catalogued as COSV52119799; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 62/138 reads (45%) | catalogued as rs747914168; called by mutect2, varscan2
- NGLY1 | c.1149G>T p.E383D | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.291); catalogued as COSV54986182, COSV99770493; called by muse, mutect2, varscan2
- NID2 | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53496360; called by muse, mutect2
- NKTR | c.1847dup p.S617Ffs*15 | Frame Shift Ins (INS) | VAF 36/85 reads (42%) | catalogued as rs763440516; called by mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 49/130 reads (38%) | catalogued as rs776154715; called by mutect2, varscan2
- NSD1 | c.6620C>A p.P2207H | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61776296; called by muse, mutect2, varscan2
- OR2AG1 | c.218T>C p.F73S | Missense Mutation (SNP) | VAF 109/252 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as COSV56626068; called by muse, mutect2, varscan2
- OR6B2 | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 90/228 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV53154236; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1358G>A p.G453E (on ENST00000259318 / NM_001136562.3; = p.G684E on NM_007203.5) | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV52176249; called by muse, mutect2, varscan2
- PASK | c.2875G>A p.A959T | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV52152624; called by muse, mutect2, varscan2
- PASK | c.1572C>G p.S524R | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.102); catalogued as COSV52152643; called by muse, mutect2, varscan2
- PCDHA11 | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV56493477; called by muse, mutect2, varscan2
- PCDHGA4 | c.731del p.T244Rfs*18 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as COSV53947159, COSV54005227; called by mutect2, pindel, varscan2
- PDPN | c.160G>T p.G54* (on ENST00000621990; = p.G130* on NM_006474.4) | Nonsense Mutation (SNP) | VAF 50/104 reads (48%) | catalogued as COSV53848247; called by muse, mutect2, varscan2
- PDZD2 | c.192dup p.E65Rfs*34 | Frame Shift Ins (INS) | VAF 34/80 reads (43%) | catalogued as rs755733994; called by mutect2, varscan2
- PGAP4 | c.967C>A p.L323M | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV66387650; called by muse, mutect2, varscan2
- PGAP4 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761442054, COSV66387322; called by muse, mutect2, varscan2
- PHF19 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV56489727; called by muse, mutect2, varscan2
- PHF21B | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.029); catalogued as rs1197836173, COSV57558304; called by muse, mutect2, varscan2
- PIK3CA | c.1483C>T p.H495Y | Missense Mutation (SNP) | VAF 126/259 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55926687; called by muse, mutect2, varscan2
- PIP5K1C | c.1532G>A p.C511Y | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs1263640826, COSV58952369; called by muse, mutect2, varscan2
- PKHD1L1 | c.5852A>G p.N1951S | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV65742893; called by muse, mutect2, varscan2
- PKP4 | c.676A>C p.I226L | Missense Mutation (SNP) | VAF 102/186 reads (55%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV67677098; called by muse, mutect2, varscan2
- PLA2G2F | c.384C>A p.H128Q | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV64279983; called by muse, mutect2, varscan2
- PLGRKT | c.227del p.K76Rfs*12 | Frame Shift Del (DEL) | VAF 62/130 reads (48%) | catalogued as rs765091847; called by mutect2, varscan2
- PLIN5 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs770558472, COSV67850688; called by muse, mutect2, varscan2
- PNO1 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 148/354 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54561424; called by muse, mutect2, varscan2
- POGZ | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as rs369950979, COSV99652579; called by muse, mutect2, varscan2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 21/46 reads (46%) | catalogued as rs745933237; called by mutect2, pindel, varscan2
- PPFIA4 | c.1801G>A p.A601T (on ENST00000447715; = p.A602T on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV55314984; called by muse, mutect2, varscan2
- PPP1R12A | c.2367T>G p.S789R | Missense Mutation (SNP) | VAF 136/297 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV54108286; called by muse, mutect2, varscan2
- PRAMEF6 | c.1289G>T p.R430I | Missense Mutation (SNP) | VAF 118/338 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1189998039; called by mutect2, varscan2
- PRPF40B | c.99del p.M34Cfs*29 (on ENST00000380281; = p.M28Cfs*29 on NM_012272.3) | Frame Shift Del (DEL) | VAF 28/88 reads (32%) | catalogued as COSV56058435; called by mutect2, pindel, varscan2
- PRPF4B | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 95/244 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV61784176; called by muse, mutect2, varscan2
- PRRC2C | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 6/170 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1271176123, COSV58905323; called by muse, mutect2
- PYCR1 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV57999250; called by muse, mutect2, varscan2
- PYCR3 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483058508, COSV55306890; called by muse, mutect2, varscan2
- RAB11FIP4 | c.944G>A p.S315N | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV57928989; called by muse, mutect2, varscan2
- RALYL | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs374650214; called by muse, mutect2, varscan2
- RAPGEF4 | c.1247A>G p.H416R | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as rs1178844428, COSV51389063; called by muse, mutect2, varscan2
- RASAL2 | c.722del p.K241Rfs*7 | Frame Shift Del (DEL) | VAF 45/137 reads (33%) | catalogued as rs771909008; called by mutect2, varscan2
- RBM33 | c.3089del p.G1030Afs*52 | Frame Shift Del (DEL) | VAF 15/27 reads (56%) | catalogued as COSV62031451; called by mutect2, pindel, varscan2
- RBM43 | c.406del p.I136Sfs*4 | Frame Shift Del (DEL) | VAF 28/81 reads (35%) | catalogued as rs142934811, CD1212851; called by mutect2, varscan2
- RBM4B | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as COSV59496946; called by muse, mutect2, varscan2
- RELN | c.8417A>G p.Q2806R | Missense Mutation (SNP) | VAF 89/188 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.766); catalogued as COSV59002102; called by muse, mutect2, varscan2
- RETREG2 | c.1339G>A p.G447S | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs199754357, COSV56087576; called by muse, mutect2, varscan2
- RSAD1 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as rs940111556, COSV51955663; called by muse, mutect2, varscan2
- RTP4 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV52018426; called by muse, mutect2, varscan2
- RUNX1 | c.614G>T p.R205L (on ENST00000344691 / NM_001001890.3; = p.R232L on NM_001754.5) | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV55867388, COSV55883399; called by muse, mutect2, varscan2
- SAFB | c.2464G>T p.G822W | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52651412; called by muse, mutect2, varscan2
- SCRN1 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54130755; called by muse, mutect2, varscan2
- SCUBE1 | c.1246del p.R416Gfs*35 | Frame Shift Del (DEL) | VAF 20/33 reads (61%) | catalogued as rs1569500148, COSV62613321; called by mutect2, varscan2
- SETD1A | c.5026G>A p.V1676M | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1231015194, COSV52680540; called by muse, mutect2, varscan2
- SGCE | c.1130G>A p.C377Y (on ENST00000647096; = p.C341Y on NM_003919.3) | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56017212; called by muse, mutect2, varscan2
- SHROOM4 | c.2648A>G p.H883R | Missense Mutation (SNP) | VAF 125/247 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV56789283; called by muse, mutect2, varscan2
- SLC10A3 | c.807del p.S270Afs*18 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs1557213591, COSV99682188; called by mutect2, pindel, varscan2
- SLC16A5 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766347239, COSV61675931; called by muse, mutect2
- SLC35G5 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 66/164 reads (40%) | catalogued as COSV55312378; called by muse, mutect2, varscan2
- SLCO4A1 | c.1352G>A p.G451D | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.61); catalogued as COSV53890870; called by muse, mutect2, varscan2
- SMARCA4 | c.4559G>A p.R1520H | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.359); catalogued as COSV60794292; called by muse, mutect2, varscan2
- SMG5 | c.839+1G>T p.X280_splice | Splice Site (SNP) | VAF 196/394 reads (50%) | catalogued as COSV62435294; called by muse, mutect2, varscan2
- SNX2 | c.977G>A p.S326N | Missense Mutation (SNP) | VAF 116/292 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV65348319; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 120/264 reads (45%) | catalogued as rs768873484; called by mutect2, varscan2
- SP140 | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 101/230 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs778717233, COSV59449804; called by muse, varscan2
- SPARCL1 | c.399dup p.L134Tfs*6 | Frame Shift Ins (INS) | VAF 140/359 reads (39%) | catalogued as rs1430929583; called by mutect2, pindel, varscan2
- SPEF2 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 112/221 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as COSV56796873; called by muse, mutect2, varscan2
- SPG7 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 103/237 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.563); catalogued as COSV51948006; called by muse, mutect2, varscan2
- SPRED2 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344058765, COSV62692890; called by muse, mutect2, varscan2
- SSBP3 | c.773A>G p.Y258C (on ENST00000371320 / NM_145716.4; = p.Y238C on NM_018070.5) | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58886685; called by muse, mutect2, varscan2
- STAT2 | c.464T>C p.M155T | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs767217369, COSV58475486; called by muse, mutect2, varscan2
- STK11 | c.762del p.F255Sfs*32 | Frame Shift Del (DEL) | VAF 30/75 reads (40%) | catalogued as CM981869, COSV58825310; called by mutect2, pindel, varscan2
- SUPT20H | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 129/317 reads (41%) | catalogued as rs926244369, COSV62247895; called by muse, mutect2, varscan2
- TAS2R4 | c.427A>G p.T143A | Missense Mutation (SNP) | VAF 124/240 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.257); catalogued as COSV56093560; called by muse, mutect2, varscan2
- TBC1D12 | c.2280G>T p.K760N | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV56554263, COSV99831340; called by muse, mutect2, varscan2
- TCHH | c.3988C>T p.R1330C | Missense Mutation (SNP) | VAF 109/224 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs748302312, COSV64274776; called by muse, mutect2, varscan2
- TECRL | c.107del p.L36Cfs*11 | Frame Shift Del (DEL) | VAF 83/223 reads (37%) | catalogued as COSV101168991; called by mutect2, pindel, varscan2
- TECTA | c.4421A>G p.N1474S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV50707748; called by muse, mutect2
- TFAM | c.441del p.E148Sfs*2 | Frame Shift Del (DEL) | VAF 29/82 reads (35%) | catalogued as rs544132101; called by mutect2, varscan2
- THBS1 | c.1773G>A p.E591= | Splice Region (SNP) | VAF 105/244 reads (43%) | catalogued as rs1457814859, COSV52952034; called by muse, mutect2, varscan2
- TICRR | c.3640C>T p.H1214Y | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.93); PolyPhen benign (0.187); catalogued as COSV51541482; called by muse, mutect2, varscan2
- TLN2 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774116063, COSV60887337; called by muse, mutect2, varscan2
- TLR7 | c.2644C>T p.Q882* | Nonsense Mutation (SNP) | VAF 70/185 reads (38%) | catalogued as COSV66124302; called by muse, mutect2, varscan2
- TMEM168 | c.1817C>T p.T606I | Missense Mutation (SNP) | VAF 98/230 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs1312693419, COSV57180692; called by muse, mutect2, varscan2
- TMEM63A | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776000468, COSV64763063; called by muse, mutect2, varscan2
- TMEM86A | c.566C>A p.S189* | Nonsense Mutation (SNP) | VAF 78/168 reads (46%) | catalogued as COSV55010736; called by muse, mutect2, varscan2
- TMPO | c.1691A>G p.Q564R | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.272); catalogued as COSV54123189; called by muse, mutect2, varscan2
- TMPRSS6 | c.2398G>A p.V800M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as rs747802959, COSV60978150, COSV60981618; called by muse, mutect2, varscan2
- TNPO3 | c.1184A>G p.D395G | Missense Mutation (SNP) | VAF 105/249 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.282); catalogued as rs771434645, COSV55281458; called by muse, mutect2, varscan2
- TRIM67 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.688); catalogued as COSV64158852; called by muse, mutect2, varscan2
- TRIML1 | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV60194272; called by muse, mutect2, varscan2
- TRPM4 | c.2732C>T p.T911M | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs148006852; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSSK3 | c.570dup p.G191Rfs*2 | Frame Shift Ins (INS) | VAF 54/133 reads (41%) | catalogued as rs756978339; called by mutect2, pindel, varscan2
- TTC29 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV57275348; called by muse, mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 135/284 reads (48%) | catalogued as rs756650873; called by mutect2, varscan2
- TTLL4 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV51436408; called by muse, mutect2, varscan2
- UBE3C | c.2904A>C p.Q968H | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV61953163; called by muse, mutect2, varscan2
- USP31 | c.2992G>A p.V998I | Missense Mutation (SNP) | VAF 113/231 reads (49%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.06); catalogued as rs762179485, COSV54852165, COSV54856077; called by muse, mutect2, varscan2
- VBP1 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1265010045, COSV53972510; called by muse, mutect2, varscan2
- VWCE | c.2666C>A p.P889H | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.258); catalogued as COSV57112494; called by muse, mutect2, varscan2
- WASF3 | c.920del p.P307Rfs*28 | Frame Shift Del (DEL) | VAF 4/15 reads (27%) | catalogued as rs756173793; called by mutect2, varscan2
- WDTC1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60088299; called by muse, mutect2, varscan2
- WFDC2 | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV54151479; called by muse, mutect2, varscan2
- WWP2 | c.2249G>T p.C750F | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63124978; called by muse, mutect2, varscan2
- YBX2 | c.490G>T p.G164W | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50300934; called by muse, mutect2, varscan2
- ZBTB14 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.34); catalogued as rs144708635; called by muse, mutect2, varscan2
- ZBTB33 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV58533947; called by muse, mutect2, varscan2
- ZCCHC7 | c.1160T>C p.I387T | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV60957387; called by muse, mutect2, varscan2
- ZCCHC7 | c.1625del p.K542Sfs*9 | Frame Shift Del (DEL) | VAF 32/88 reads (36%) | catalogued as rs760783608; called by mutect2, varscan2
- ZFP90 | c.1780del p.T594Pfs*57 | Frame Shift Del (DEL) | VAF 62/129 reads (48%) | catalogued as rs747260313; called by mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 142/390 reads (36%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF462 | c.4588G>A p.V1530I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs762506887, COSV52938225; called by muse, mutect2, varscan2
- ZNF48 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60783251; called by muse, mutect2, varscan2
- ZNF511 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV62920111; called by muse, mutect2, varscan2
- ZNF653 | c.1298G>A p.S433N | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53403019; called by muse, mutect2, varscan2
- ZNF688 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV56300750, COSV56301802; called by muse, mutect2, varscan2
- ZNF699 | c.209A>G p.Q70R | Missense Mutation (SNP) | VAF 94/181 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100426828, COSV58025616; called by muse, mutect2, varscan2
- ZNF862 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 244/532 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.625); catalogued as rs756335788, COSV56223911; called by muse, mutect2, varscan2
- ABCA12 | c.5689dup p.R1897Kfs*18 (on ENST00000272895 / NM_173076.3; = p.R1579Kfs*18 on NM_015657.3) | Frame Shift Ins (INS) | VAF 112/266 reads (42%) | called by mutect2, pindel, varscan2
- ABCA8 | c.4413dup p.D1472Rfs*41 | Frame Shift Ins (INS) | VAF 79/249 reads (32%) | called by mutect2, pindel, varscan2
- AKAP12 | c.4382dup p.N1461Kfs*2 | Frame Shift Ins (INS) | VAF 42/94 reads (45%) | called by mutect2, varscan2
- ARID1A | c.4403del p.P1468Lfs*13 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- ARMCX3 | c.1070del p.L357Wfs*2 | Frame Shift Del (DEL) | VAF 28/69 reads (41%) | called by mutect2, pindel, varscan2
- ASAP2 | c.2795dup p.A933Cfs*5 | Frame Shift Ins (INS) | VAF 79/228 reads (35%) | called by mutect2, pindel, varscan2
- ASPM | c.2023del p.T675Qfs*33 | Frame Shift Del (DEL) | VAF 234/607 reads (39%) | called by mutect2, pindel, varscan2
- BEND2 | c.2299dup p.R767Kfs*3 | Frame Shift Ins (INS) | VAF 60/164 reads (37%) | called by mutect2, pindel, varscan2
- BICRAL | c.2689del p.T897Qfs*8 | Frame Shift Del (DEL) | VAF 40/105 reads (38%) | called by mutect2, pindel, varscan2
- BOD1L1 | c.1707del p.V570* | Frame Shift Del (DEL) | VAF 95/198 reads (48%) | called by mutect2, varscan2
- CDKN2AIP | c.116dup p.L39Ffs*18 | Frame Shift Ins (INS) | VAF 10/14 reads (71%) | called by mutect2, varscan2
- CEND1 | c.373del p.L125Cfs*12 | Frame Shift Del (DEL) | VAF 17/39 reads (44%) | called by mutect2, pindel, varscan2
- CENPC | c.2602del p.S868Lfs*5 | Frame Shift Del (DEL) | VAF 120/311 reads (39%) | called by mutect2, pindel, varscan2
- CFAP61 | c.898del p.I300* | Frame Shift Del (DEL) | VAF 59/155 reads (38%) | called by mutect2, pindel, varscan2
- CLCN6 | c.1288del p.C430Vfs*73 | Frame Shift Del (DEL) | VAF 88/207 reads (43%) | called by mutect2, pindel, varscan2
- CLIP3 | c.1022del p.G341Afs*164 | Frame Shift Del (DEL) | VAF 38/92 reads (41%) | called by mutect2, pindel, varscan2
- CRTC3 | c.316del p.L106Sfs*48 | Frame Shift Del (DEL) | VAF 43/137 reads (31%) | called by mutect2, pindel, varscan2
- DCC | c.3491dup p.N1164Kfs*3 | Frame Shift Ins (INS) | VAF 55/130 reads (42%) | called by mutect2, pindel, varscan2
- DDX52 | c.1664del p.K555Rfs*2 | Frame Shift Del (DEL) | VAF 167/427 reads (39%) | called by mutect2, pindel, varscan2
- DENND4A | c.966del p.F322Lfs*8 | Frame Shift Del (DEL) | VAF 106/214 reads (50%) | called by mutect2, varscan2
- DENND5B | c.1411del p.M471Wfs*14 | Frame Shift Del (DEL) | VAF 69/177 reads (39%) | called by mutect2, pindel, varscan2
- EIF2AK4 | c.574del p.R192Gfs*43 | Frame Shift Del (DEL) | VAF 72/207 reads (35%) | called by mutect2, pindel, varscan2
- FAM81B | c.1190del p.G397Vfs*3 | Frame Shift Del (DEL) | VAF 69/154 reads (45%) | called by mutect2, varscan2
- FAT1 | c.8077dup p.I2693Nfs*38 | Frame Shift Ins (INS) | VAF 50/128 reads (39%) | called by mutect2, pindel, varscan2
- H2AC20 | c.346_347del p.L116Vfs*27 | Frame Shift Del (DEL) | VAF 42/92 reads (46%) | called by mutect2, pindel, varscan2
- HBZ | c.88_89del p.L30Gfs*146 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | called by pindel, varscan2
- HYDIN | c.13817dup p.N4606Kfs*61 | Frame Shift Ins (INS) | VAF 40/186 reads (22%) | called by mutect2, pindel, varscan2
- IGLON5 | c.276del p.E93Rfs*44 | Frame Shift Del (DEL) | VAF 15/28 reads (54%) | called by mutect2, pindel, varscan2
- INPP5D | c.1253del p.P418Lfs*31 (on ENST00000445964 / NM_001017915.3; = p.P417Lfs*31 on NM_005541.5) | Frame Shift Del (DEL) | VAF 32/93 reads (34%) | called by mutect2, pindel, varscan2
- IPO8 | c.1234del p.M412* | Frame Shift Del (DEL) | VAF 106/264 reads (40%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 84/184 reads (46%) | called by mutect2, varscan2
- KBTBD6 | c.1326del p.R443Efs*9 | Frame Shift Del (DEL) | VAF 36/111 reads (32%) | called by mutect2, pindel, varscan2
- KMT2B | c.7384del p.A2462Rfs*43 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- LAMA5 | c.976C>A p.H326N | Missense Mutation (SNP) | VAF 2/13 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MGAT4B | c.658del p.H220Tfs*34 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- MYO7B | c.1283del p.N428Mfs*77 | Frame Shift Del (DEL) | VAF 66/171 reads (39%) | called by mutect2, pindel, varscan2
- OTOF | c.1681del p.E561Rfs*18 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- PGM1 | c.1597del p.Q533Rfs*12 | Frame Shift Del (DEL) | VAF 60/141 reads (43%) | called by mutect2, pindel, varscan2
- POTEA | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPL | c.3821del p.K1274Rfs*6 | Frame Shift Del (DEL) | VAF 85/220 reads (39%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.1255dup p.R419Pfs*7 | Frame Shift Ins (INS) | VAF 89/154 reads (58%) | called by mutect2, pindel, varscan2
- PRB2 | c.803dup p.Q269Tfs*156 | Frame Shift Ins (INS) | VAF 50/234 reads (21%) | called by pindel, varscan2
- PXDN | c.2592del p.N865Mfs*25 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- RAB5A | c.163+1del | Frame Shift Del (DEL) | VAF 88/244 reads (36%) | called by mutect2, pindel, varscan2
- RALGAPB | c.2912del p.F971Sfs*53 | Frame Shift Del (DEL) | VAF 111/295 reads (38%) | called by mutect2, pindel, varscan2
- RASA1 | c.248del p.G83Efs*4 | Frame Shift Del (DEL) | VAF 30/83 reads (36%) | called by mutect2, pindel, varscan2
- RCL1 | c.343del p.I115* | Frame Shift Del (DEL) | VAF 138/367 reads (38%) | called by mutect2, pindel, varscan2
- SACS | c.9081del p.F3027Lfs*25 | Frame Shift Del (DEL) | VAF 60/192 reads (31%) | called by mutect2, pindel, varscan2
- SCAF4 | c.359del p.N120Mfs*25 | Frame Shift Del (DEL) | VAF 77/233 reads (33%) | called by mutect2, pindel, varscan2
- SETBP1 | c.1261del p.R421Dfs*23 | Frame Shift Del (DEL) | VAF 41/101 reads (41%) | called by mutect2, pindel, varscan2
- SLC16A11 | c.784dup p.Y262Lfs*140 (on ENST00000308009; = p.Y238Lfs*140 on NM_153357.3) | Frame Shift Ins (INS) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- SLC17A5 | c.397dup p.I133Nfs*62 | Frame Shift Ins (INS) | VAF 105/259 reads (41%) | called by mutect2, pindel, varscan2
- SMARCA1 | c.1497dup p.E500Rfs*29 | Frame Shift Ins (INS) | VAF 68/175 reads (39%) | called by mutect2, pindel, varscan2
- SYCP2 | c.3604dup p.I1202Nfs*14 | Frame Shift Ins (INS) | VAF 150/346 reads (43%) | called by mutect2, varscan2
- TARBP1 | c.1249-5_1249-2del p.X417_splice | Splice Site (DEL) | VAF 3/26 reads (12%) | called by pindel, varscan2*
- TEX10 | c.1186_1187del p.M396Efs*20 | Frame Shift Del (DEL) | VAF 134/370 reads (36%) | called by mutect2, pindel, varscan2
- TMC8 | c.1480del p.L494Cfs*5 | Frame Shift Del (DEL) | VAF 43/110 reads (39%) | called by mutect2, pindel, varscan2
- TNC | c.733del p.A245Lfs*20 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | called by mutect2, pindel, varscan2
- TNRC18 | c.7366del p.E2456Rfs*44 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, varscan2
- TNRC6C | c.1473dup p.K492Efs*56 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- TRBV27 | c.10del p.Q4Sfs*11 | Frame Shift Del (DEL) | VAF 61/146 reads (42%) | called by mutect2, pindel, varscan2
- TRBV3-1 | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIO | c.5590del p.A1864Pfs*32 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- TTBK2 | c.1735del p.S579Lfs*22 | Frame Shift Del (DEL) | VAF 78/231 reads (34%) | called by mutect2, pindel, varscan2
- TTLL2 | c.1324dup p.S442Kfs*2 | Frame Shift Ins (INS) | VAF 67/148 reads (45%) | called by mutect2, pindel, varscan2
- TTN | c.10949del p.P3650Lfs*69 (on ENST00000591111; = p.P3604Lfs*69 on NM_003319.4) | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | called by mutect2, pindel, varscan2
- UBP1 | c.1139del p.N380Tfs*19 | Frame Shift Del (DEL) | VAF 77/249 reads (31%) | called by mutect2, pindel, varscan2
- UBQLN1 | c.441del p.F147Lfs*3 | Frame Shift Del (DEL) | VAF 125/360 reads (35%) | called by mutect2, pindel, varscan2
- VPS13A | c.1595+4_1595+7del p.X532_splice | Splice Site (DEL) | VAF 28/108 reads (26%) | called by pindel, varscan2
- ZNF205 | c.1333del p.V445Sfs*92 | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | called by mutect2, pindel, varscan2
- ADGRF3 | c.1974G>A p.V658= (on ENST00000311519 / NM_001145168.1; = p.V459= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as COSV61050271; called by muse, mutect2, varscan2
- ALDH9A1 | c.699G>A p.V233= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs561795333, COSV61339841; called by muse, mutect2, varscan2
- ALK | c.2460A>G p.G820= | Silent (SNP) | VAF 111/257 reads (43%) | catalogued as COSV66568249; called by muse, mutect2, varscan2
- AMIGO1 | c.324G>A p.P108= | Silent (SNP) | VAF 82/181 reads (45%) | catalogued as COSV63990384, COSV63990450; called by muse, mutect2, varscan2
- ARFGEF3 | c.4824C>T p.C1608= | Silent (SNP) | VAF 55/137 reads (40%) | catalogued as COSV52457345; called by muse, mutect2, varscan2
- ARMCX2 | c.1074C>T p.T358= | Silent (SNP) | VAF 62/139 reads (45%) | catalogued as COSV57529463, COSV57530056; called by muse, mutect2, varscan2
- ATP1A4 | c.1701G>A p.L567= | Silent (SNP) | VAF 79/195 reads (41%) | catalogued as COSV63625330, COSV63626489; called by muse, mutect2, varscan2
- BPIFB6 | c.69G>A p.L23= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs770600762, COSV62755201; called by muse, mutect2
- BRINP2 | c.2163T>C p.I721= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV64177525; called by muse, mutect2, varscan2
- CHAT | c.1266C>T p.Y422= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs201381950, COSV60321515; called by muse, mutect2, varscan2
- CPXM1 | c.744G>T p.V248= | Silent (SNP) | VAF 59/105 reads (56%) | catalogued as COSV66045383; called by muse, mutect2, varscan2
- CYP11B2 | c.1128C>T p.Y376= | Silent (SNP) | VAF 52/122 reads (43%) | catalogued as COSV59995880, COSV59998366; called by muse, mutect2, varscan2
- CYREN | c.255G>A p.A85= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs377368963, COSV51965422, COSV51966209; called by muse, mutect2, varscan2
- DAAM2 | c.2347C>T p.L783= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs1472099724, COSV51317765; called by muse, mutect2, varscan2
- DAPK2 | c.726G>A p.V242= | Silent (SNP) | VAF 78/172 reads (45%) | catalogued as COSV56045486; called by muse, mutect2, varscan2
- DIPK1B | c.898C>T p.L300= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs1008360279, COSV63038039; called by muse, mutect2, varscan2
- DMWD | c.828G>A p.P276= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs144009493; called by muse, mutect2, varscan2
- DOCK6 | c.2988C>T p.S996= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV53914821; called by muse, mutect2, varscan2
- FADS6 | c.162C>T p.D54= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1049178619, COSV59602523; called by muse, mutect2, varscan2
- FAT1 | c.12846C>T p.P4282= | Silent (SNP) | VAF 61/149 reads (41%) | catalogued as rs1388880480, COSV71673902; called by muse, mutect2, varscan2
- FLNA | c.2472C>T p.F824= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs782669943, COSV61037923; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- FUT2 | c.231C>T p.G77= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as rs201304120, COSV67179297; called by muse, mutect2, varscan2
- GGT1 | c.774T>C p.A258= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV50640344; called by muse, mutect2, varscan2
- GIGYF2 | c.3063G>A p.Q1021= | Silent (SNP) | VAF 46/83 reads (55%) | catalogued as rs1164448136, COSV65249402; called by muse, mutect2, varscan2
- GPR37L1 | c.1329G>A p.S443= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs758707358, COSV55343252; called by muse, mutect2, varscan2
- GPR50 | c.1065T>C p.C355= | Silent (SNP) | VAF 52/141 reads (37%) | catalogued as COSV54439076; called by muse, mutect2, varscan2
- GPRASP2 | c.1551C>T p.P517= | Silent (SNP) | VAF 36/69 reads (52%) | catalogued as rs756156084, COSV59991249; called by muse, mutect2, varscan2
- GSTP1 | c.561G>C p.R187= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV66992459; called by muse, mutect2, varscan2
- HDAC9 | c.138G>A p.L46= | Silent (SNP) | VAF 14/141 reads (10%) | catalogued as rs1425384570, COSV67773201; called by muse, mutect2, varscan2
- HERC1 | c.3586C>T p.L1196= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV71247809; called by muse, mutect2
- HERC2 | c.2496G>A p.T832= | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as rs745836275, COSV55323626; called by muse, mutect2, varscan2
- HLX | c.1293C>T p.G431= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV65044831; called by muse, mutect2
- IL4R | c.2331G>A p.P777= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs200822191, COSV50138084; called by muse, mutect2, varscan2
- IQGAP1 | c.4110C>T p.D1370= | Silent (SNP) | VAF 74/160 reads (46%) | catalogued as rs528193427, COSV51585606; called by muse, mutect2, varscan2
- ISYNA1 | c.1599G>A p.P533= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as rs536858921, COSV54209550; called by muse, mutect2, varscan2
- ITGAX | c.2442C>A p.S814= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV51645643; called by muse, mutect2, varscan2
- KEAP1 | c.492C>T p.I164= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as rs757575410, COSV50282861; called by muse, mutect2, varscan2
- KIAA1614 | c.363C>T p.G121= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV62552838; called by muse, mutect2, varscan2
- LILRA2 | c.864C>A p.S288= | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as COSV52191576; called by muse, mutect2, varscan2
- LMTK3 | c.2577G>A p.T859= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs757177302, COSV54312294; called by muse, mutect2, varscan2
- LRRK1 | c.2601G>A p.V867= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV52611511; called by muse, mutect2, varscan2
- MADD | c.3681C>T p.G1227= | Silent (SNP) | VAF 84/194 reads (43%) | catalogued as COSV60624067; called by muse, mutect2, varscan2
- MEGF10 | c.2094C>T p.D698= | Silent (SNP) | VAF 76/185 reads (41%) | catalogued as COSV57249146; called by muse, mutect2, varscan2
- MN1 | c.2601C>T p.G867= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV56558372; called by muse, mutect2, varscan2
- MSN | c.1689G>A p.R563= | Silent (SNP) | VAF 61/115 reads (53%) | catalogued as COSV64304027; called by muse, mutect2, varscan2
- MTX2 | c.408A>G p.T136= | Silent (SNP) | VAF 126/298 reads (42%) | catalogued as COSV50888076; called by muse, mutect2, varscan2
- MUC16 | c.19425A>G p.S6475= | Silent (SNP) | VAF 134/381 reads (35%) | catalogued as COSV67465634; called by muse, mutect2, varscan2
- NFRKB | c.2649T>C p.P883= (on ENST00000446488 / NM_001143835.2; = p.P908= on NM_006165.3) | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV58758012; called by muse, mutect2, varscan2
- NFRKB | c.2298A>G p.S766= (on ENST00000446488 / NM_001143835.2; = p.S791= on NM_006165.3) | Silent (SNP) | VAF 57/134 reads (43%) | catalogued as COSV58758020; called by muse, mutect2, varscan2
- OR51B6 | c.615C>T p.V205= | Silent (SNP) | VAF 197/492 reads (40%) | catalogued as rs766271397, COSV66512970, COSV66513007; called by muse, mutect2, varscan2
- PAXIP1 | c.366G>A p.T122= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as rs1024057366, COSV68185391; called by muse, mutect2, varscan2
- PDZD2 | c.1884C>T p.D628= | Silent (SNP) | VAF 112/216 reads (52%) | catalogued as rs754199194, COSV56858319; called by muse, mutect2, varscan2
- PID1 | c.597C>T p.A199= (on ENST00000354069 / NM_001330156.1; = p.A197= on NM_017933.5) | Silent (SNP) | VAF 76/161 reads (47%) | catalogued as rs542027380, COSV62475637; called by muse, mutect2, varscan2
- PIGR | c.1194G>A p.L398= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV62904019; called by muse, mutect2, varscan2
- PLEKHG5 | c.318G>A p.T106= (on ENST00000400915 / NM_001042663.3; = p.T69= on NM_020631.6) | Silent (SNP) | VAF 13/175 reads (7%) | catalogued as rs1220408894, COSV61702045; called by muse, mutect2
- PPP1R3C | c.387C>T p.H129= | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as rs763830391, COSV53288231; called by muse, mutect2, varscan2
- PRKCB | c.450G>A p.L150= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs761578978, COSV57779714, COSV57798389; called by muse, mutect2, varscan2
- PSAP | c.240T>C p.N80= | Silent (SNP) | VAF 7/146 reads (5%) | catalogued as COSV67550350; called by muse, mutect2
- PTPRB | c.2040T>C p.H680= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as COSV54240451; called by muse, mutect2, varscan2
- RAB20 | c.414G>A p.G138= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV57440590; called by muse, mutect2, varscan2
- RREB1 | c.3963G>A p.P1321= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs770076990, COSV58558001; called by muse, mutect2, varscan2
- RTL8C | c.132C>T p.I44= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as rs753746466, COSV57060086; called by muse, mutect2, varscan2
- SIMC1 | c.147A>G p.T49= (on ENST00000443967 / NM_001308196.1; = p.T68= on NM_001308195.2) | Silent (SNP) | VAF 110/243 reads (45%) | catalogued as COSV57903312; called by muse, mutect2, varscan2
- SLC2A8 | c.819C>T p.N273= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as rs372199931; called by muse, mutect2, varscan2
- SOAT2 | c.639G>A p.A213= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs1308224266, COSV56859486; called by muse, mutect2, varscan2
- TBC1D9 | c.2277C>T p.S759= | Silent (SNP) | VAF 123/299 reads (41%) | catalogued as rs780935553, COSV71307499; called by muse, mutect2, varscan2
- TEX15 | c.3258A>G p.L1086= (on ENST00000256246; = p.L1469= on NM_001350162.2) | Silent (SNP) | VAF 103/244 reads (42%) | catalogued as COSV56346488; called by muse, mutect2, varscan2
- TGIF2LX | c.420G>T p.A140= | Silent (SNP) | VAF 65/147 reads (44%) | catalogued as COSV52213290, COSV52213984; called by muse, mutect2, varscan2
- THEMIS | c.579T>C p.P193= | Silent (SNP) | VAF 115/242 reads (48%) | catalogued as COSV64071136; called by muse, mutect2, varscan2
- TLR2 | c.2070T>C p.I690= | Silent (SNP) | VAF 5/140 reads (4%) | catalogued as COSV52606319; called by muse, mutect2
- TMPRSS12 | c.246C>T p.T82= | Silent (SNP) | VAF 72/149 reads (48%) | catalogued as COSV68256319; called by muse, mutect2, varscan2
- TRIM38 | c.369G>A p.G123= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV62642160; called by muse, mutect2, varscan2
- TRIM68 | c.1042C>T p.L348= | Silent (SNP) | VAF 77/162 reads (48%) | catalogued as rs755678446, COSV56168475; called by muse, mutect2, varscan2
- TRIM75P | c.1368A>G p.S456= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as COSV72295841; called by muse, mutect2, varscan2
- TYRO3 | c.1608G>A p.Q536= | Silent (SNP) | VAF 156/354 reads (44%) | catalogued as COSV55483223; called by muse, mutect2, varscan2
- XRN2 | c.1626C>T p.Y542= | Silent (SNP) | VAF 138/288 reads (48%) | catalogued as rs143832454; called by muse, mutect2, varscan2
- ZNF22 | c.102C>T p.G34= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as COSV53583992; called by muse, mutect2, varscan2
- ZNF236 | c.2853A>G p.Q951= | Silent (SNP) | VAF 45/90 reads (50%) | catalogued as COSV53488279; called by muse, mutect2, varscan2
- ZNF750 | c.906C>T p.Y302= | Silent (SNP) | VAF 123/276 reads (45%) | catalogued as rs772392011, COSV53958592, COSV53958606, COSV53960261, COSV53961789; called by muse, mutect2, varscan2
- CLDN6 | c.*2G>A | 3'UTR (SNP) | VAF 21/47 reads (45%) | catalogued as rs926164295, COSV100172010; called by muse, mutect2, varscan2
- DST | c.4297-1519C>G | Intron (SNP) | VAF 39/88 reads (44%) | catalogued as COSV99749364; called by muse, mutect2, varscan2
- IRF5 | c.482-20A>G | Intron (SNP) | VAF 15/38 reads (39%) | catalogued as COSV50857605; called by muse, mutect2, varscan2
- MEX3D | c.*205C>T | 3'UTR (SNP) | VAF 17/38 reads (45%) | catalogued as rs1265864208, COSV101183448; called by muse, mutect2, varscan2
- NVL | c.2183-6718del | Intron (DEL) | VAF 83/201 reads (41%) | catalogued as rs573934358; called by mutect2, varscan2
- PTGFR | c.798+4403G>T | Intron (SNP) | VAF 111/255 reads (44%) | catalogued as COSV100882299, COSV66115011; called by muse, mutect2, varscan2
- RBM44 | c.-98-2821dup | Intron (INS) | VAF 30/66 reads (45%) | catalogued as rs746070623; called by mutect2, varscan2
- SSX9P | n.238A>G | RNA (SNP) | VAF 238/564 reads (42%) | called by muse, mutect2, varscan2
- TTN | c.34265-4195del | Intron (DEL) | VAF 120/242 reads (50%) | called by mutect2, varscan2
